Surgical pathology report (de-identified scan), TCGA case TCGA-EE-A3J3, project TCGA-SKCM (Skin Cutaneous Melanoma), tissue source site University of Sydney, specimen TCGA-EE-A3J3-06A (Metastatic).

LABORATORY SERVICE

REPORT COPY
from

DEPARTMENT OF ANATOMICAL PATHOLOGY

Enquiries

REQUESTING DR :
VERIFIED BY :

SPECIMEN DATE :
ACCESSION :

REPORTED BY
Reported by:

Previous Lab. Ref:

CLINICAL INFORMATION

Melanoma left axilla after dissection.

OPERATION/NATURE OF SPEC

E/o axillary recurrence.

ICD-0-3
Melanoma, amelanotic 8730/3
CQCF - Site: lymph node, axilla C77.3
Path Subcutaneous, axilla C49.3 lw 12/13/11

MACROSCOPIC DESCRIPTION

"Nodule left axilla". An ellipse of skin, 95 x 30mm bearing a pale linear scar 52mm in length with underlying fatty tissue, 98 x 55 x 36mm (as dictated). On sectioning there is a white nodule, 16 x 17 x 16mm which ends macroscopically to less than 1mm from the resection margin. No other lesions are seen on serially slicing the remainder of the specimen.

A&B. Tumour nodule and deep margin.
C. Overlying skin.

MICROSCOPIC DESCRIPTION

"Nodule left axilla". Metastatic amelanotic malignant melanoma in subcutis. The tumour is about 1mm from the nearest inked margin of excision.

SNOMED CODES

Axilla - malignant melanoma, metastatic
Skin resection

***** END OF ACCESSION *****

IPAX Discrepancy		X
Pro or Malignancy History		X
Case is (circled):	CONFIRMED	DISQUALIFIED

* Continued next page *

Printed on

Page 7

Source: NCI Genomic Data Commons file 01e491ba-59d1-46a5-a6f1-f92846f2d739 (TCGA-EE-A3J3.DAE45D1C-F834-48DD-A557-44F38B1C0C43.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).